CCDI case PBCVFU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/ffd568ac-ff4d-4261-99dc-c9d98c132d7a

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E0MIL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E0MJB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0MJV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
